Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3521, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3521-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Resectate of portion of colon (sigmoid colon) with an ulcerated colon carcinoma conforming to the histological type of a moderately differentiated colorectal adenocarcinoma, extending no closer than 6 cm to the resection margin and with a greatest diameter of 3 cm. Invasive spread of tumor within all layers of the intestinal wall and as far as the neighboring mesocolic fatty tissue.

Remainder of the intestinal mucosal membrane with a small, tubular adenoma with mild epithelial dysplasia (synonym: low-grade intra-epithelial neoplasia).

Oral and aboral resection margins tumor-free.

Twenty-two mesocolic lymph nodes with uncharacteristic reactive changes and tumor-free.

Tumor stage thus pT3 pN0 (0/22) L0 V0; G2.

Source: NCI Genomic Data Commons file 384fe6fb-18ca-4530-b0aa-2113a6b89e1f (TCGA-AA-3521.C3B59AEA-87DD-4434-B915-8CF262ECA259.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).